Somatic mutation profile of tumor specimen TARGET-10-PANTRY-09A (aliquot TARGET-10-PANTRY-09A-01D) from TARGET case TARGET-10-PANTRY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,656 days).
Specimen TARGET-10-PANTRY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4df8d25-b2d8-4f24-8ca0-523aa6f98819.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTRY-14A (Bone Marrow Normal), aliquot TARGET-10-PANTRY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e75c9f5b-9935-4937-b79f-68095341813a

The open-access MAF lists 42 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Intron 6, 3'UTR 2, RNA 2, Nonsense Mutation 2, Splice Site 2, 5'UTR 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBL1XR1 | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553810255, COSV70499648, COSV70501007, COSV70504550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACE | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52004764; called by muse, mutect2, varscan2
- CSMD1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV101212170; called by muse, mutect2, varscan2
- DLG1 | c.1897G>A p.G633S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as rs752886711, COSV58380394; called by muse, mutect2, varscan2
- INPP5J | c.2193+1G>C p.X731_splice (on ENST00000331075 / NM_001284285.2; = p.X363_splice on NM_001002837.2) | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as rs759666552; called by muse, mutect2, varscan2
- INPP5J | c.2515-1G>C p.X839_splice (on ENST00000331075 / NM_001284285.2; = p.X471_splice on NM_001002837.2) | Splice Site (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99311423; called by muse, mutect2, varscan2
- KIF27 | c.2273C>G p.S758C | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.921); catalogued as COSV52826217, COSV52830400; called by muse, mutect2, varscan2
- MAB21L3 | c.114G>C p.L38F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65674230; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDXDC1 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs1229188257; called by muse, mutect2, varscan2
- ZNF724 | c.1808C>G p.S603* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as rs757239720; called by muse, mutect2, varscan2
- ABHD17C | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP12 | c.4449_4450insGACCCG p.S1483_T1484insDP | In Frame Ins (INS) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- AP002748.5 | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ITGAV | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, varscan2
- ITGB3 | c.1598T>C p.V533A | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCAM2 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NDST4 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPC1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THNSL1 | c.1385G>C p.G462A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- ZMAT1 | c.1683G>C p.R561S | Missense Mutation (SNP) | VAF 57/63 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ZNF724 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- ANKRD11 | c.3318G>A p.K1106= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- GRM1 | c.2988C>T p.T996= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99265813; called by muse, mutect2, varscan2
- IL1R2 | c.585C>T p.H195= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as rs146582170; called by muse, mutect2, varscan2
- INPP5J | c.1671G>C p.L557= (on ENST00000331075 / NM_001284285.2; = p.L189= on NM_001002837.2) | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- KCNJ4 | c.528G>A p.A176= | Silent (SNP) | VAF 46/81 reads (57%) | catalogued as rs750811490, COSV57856499; called by muse, mutect2, varscan2
- PRDM15 | c.1039C>T p.L347= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV54161136; called by muse, mutect2, varscan2
- SCN7A | c.2937C>T p.F979= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV69274790; called by muse, mutect2, varscan2
- WDR64 | c.546C>T p.T182= | Silent (SNP) | VAF 45/69 reads (65%) | catalogued as rs367649063; called by muse, mutect2, varscan2
- ADAM8 | c.957+65C>T | Intron (SNP) | VAF 36/70 reads (51%) | catalogued as rs996964284; called by muse, mutect2, varscan2
- C16orf91 | c.32+11C>G | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as rs1429433005; called by muse, mutect2, varscan2
- ETFDH | c.-4G>C | 5'UTR (SNP) | VAF 24/52 reads (46%) | catalogued as rs370079385, COSV100309959; called by muse, mutect2, varscan2
- FAH | chr15:80186408 C>A | 3'Flank (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2, varscan2
- GABRA1 | c.1060-42C>G | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- GABRA1 | c.*11C>G | 3'UTR (SNP) | VAF 54/97 reads (56%) | called by muse, mutect2, varscan2
- GTF2E1 | c.*62G>A | 3'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2
- MIR4477B | n.81A>T | RNA (SNP) | VAF 9/18 reads (50%) | catalogued as rs4928837; called by muse, varscan2
- NTM-AS1 | n.1892G>C | RNA (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100868245; called by muse, mutect2, varscan2
- OTUD6B | c.316-1733C>T | Intron (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- RNF170 | c.507+185G>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- SLFN13 | c.-13-13C>G | Intron (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
